Gene-level copy-number profile of tumor specimen TCGA-EE-A29D-06A from TCGA case TCGA-EE-A29D, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 87.3 years (31,876 days).
Specimen TCGA-EE-A29D-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.50b86cfd-9c6a-4752-b5bd-81b8a58ca6e4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07d32144-ca59-4582-b842-5ff14b061580

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 142; copy number 2: 13,392; copy number 3: 9,778; copy number 4: 17,859; copy number 5: 13,877; copy number 6: 3,268; copy number 7: 1,204; copy number 8: 385; copy number 9: 41; copy number 10: 11; copy number 11: 126; copy number 12: 13; copy number 13: 25; copy number 15: 100.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29D-06A-11D-A191-01): tumor purity 0.95, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,601,882–17,670,571, 15 genes: AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22.
- chr9:21,638,285–22,824,213, 20 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 316 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,395,943–72,282,539, 1 gene, copy number 11 (within-gene range 2–11): NEGR1.
- chr1:71,794,232–73,749,623, 14 genes, copy number 11–13: NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50.
- chr1:157,745,733–157,949,071, 5 genes, copy number 9 (within-gene range 5–9): FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1.
- chr1:160,670,778–160,949,922, 13 genes, copy number 12 (within-gene range 8–12): AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4.
- chr1:164,343,005–164,357,364, 3 genes, copy number 9: NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:184,790,724–184,974,508, 1 gene, copy number 11 (within-gene range 7–11): NIBAN1.
- chr1:184,999,710–185,157,072, 5 genes, copy number 11: LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L.
- chr1:192,158,462–192,185,815, 1 gene, copy number 9: RGS18.
- chr1:192,246,708–192,367,285, 3 genes, copy number 9: AL513175.1, AL513175.2, RGS21.
- chr1:208,022,242–208,270,667, 4 genes, copy number 9 (within-gene range 5–9): PLXNA2, AL590138.1, AL606753.1, AL606753.2.
- chr1:215,376,484–215,394,418, 2 genes, copy number 10: VDAC1P10, AL450990.1.
- chr1:220,448,516–220,664,461, 7 genes, copy number 9 (within-gene range 5–9): AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2.
- chr1:228,735,479–229,042,591, 5 genes, copy number 9: RHOU, AL078624.2, AL078624.1, LINC02815, ISCA1P2.
- chr1:231,626,790–232,041,272, 1 gene, copy number 9 (within-gene range 5–9): DISC1.
- chr1:231,767,464–231,945,233, 3 genes, copy number 9 (within-gene range 5–9): AL136171.2, AL136171.1, DISC1-IT1.
- chr1:240,142,670–240,179,644, 4 genes, copy number 10: AL359918.1, Y_RNA, ADH5P3, AL359918.2.
- chr1:240,775,514–241,357,230, 1 gene, copy number 9 (within-gene range 6–9): RGS7.
- chr1:241,132,272–241,364,054, 3 genes, copy number 9: MIR3123, AL592076.1, AL359764.1.
- chr1:245,614,773–245,676,478, 2 genes, copy number 9: AC104462.2, AC104462.1.
- chr2:36,696,690–37,084,372, 5 genes, copy number 10 (within-gene range 6–10): VIT, STRN, AC007382.1, RNU6-577P, HEATR5B.
- chr2:46,580,937–46,670,778, 3 genes, copy number 9 (within-gene range 6–9): PIGF, CRIPT, AC020604.1.
- chr22:16,405,330–16,821,699, 23 genes, copy number 13: AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3.
- chr22:17,518,676–21,451,463, 207 genes, copy number 11–15 (within-gene range 5–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
